FM case AD2432 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/dbd3a5c0-ba0b-4751-981d-945a5b9ad9a0

Female, 27.3 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
